Gene-level copy-number profile of tumor specimen ALCH-B266-TTP1-A from ALCHEMIST case ALCH-B266, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.8 years (22,576 days).
Specimen ALCH-B266-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b409092c-c08e-4fa4-8bec-a7ff719345c7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B266-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/57b1792f-10d3-4a86-86a7-8c2e7d615038

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 7; copy number 2: 6,953; copy number 3: 18,723; copy number 4: 26,118; copy number 5: 1,764; copy number 6: 3,087; copy number 7: 36; copy number 8: 28; copy number 10: 27; copy number 11: 1,892; copy number 12: 273.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr22:38,952,741–38,992,804, 2 genes (within-gene range 0–2): APOBEC3A, APOBEC3B.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,192 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 679 genes, copy number 11–12 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,494 genes, copy number 10–12 (broad region; genes not listed).
- chr10:3,223,816–4,243,912, 14 genes, copy number 10: AL451164.1, LINC02668, AL139280.1, LINC02669, AL357833.1, AL450322.2, AL450322.1, KLF6, LINC02639, LINC02660, MIR6078, AC025822.1, AC025822.2, LINC00702.
- chr19:58,319,277–58,342,332, 3 genes, copy number 10: AC010642.1, ZSCAN22, MIR6806.
- chr21:43,107,942–43,168,646, 1 gene, copy number 10 (within-gene range 7–10): AP001631.2.
- chr21:43,159,066–43,162,277, 1 gene, copy number 10: AP001631.1.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
